Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6942, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6942-01A (Primary Tumor).

[page 1 of 3]
**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to [REDACTED] the section "SPECIMEN" may have been added. ****

SUPPLEMENTAL REPORT

DIAGNOSIS:

- (E) MANDIBLE:
POORLY DIFFERENTIATED SQUAMOUS CARCINOMA IN PERIOSTEUM.
Mandible margins of resection free of tumor.

DIAGNOSIS

- (A) MIDLINE UPPER LIP BIOPSIES:
SQUAMOUS CARCINOMA TUMOR AT MARGINS.
- (B) LEFT BUCCAL BIOPSY:
Squamous mucosa with hyperplasia and chronic inflammation.
No tumor present.
- (C) LEFT FLOOR OF MOUTH:
INVASIVE SQUAMOUS CARCINOMA.
- (D) LEFT UPPER LIP:
SQUAMOUS CARCINOMA GRADE 2, MARGINS AND BASE FREE.
- (E) LEFT MANDIBULECTOMY WITH RESECTION OF FLOOR OF MOUTH AND PARTIAL GLOSSECTOMY:
INVASIVE POORLY DIFFERENTIATED SQUAMOUS CARCINOMA, MARGINS OF RESECTION FREE OF CARCINOMA. FOCAL MODERATE DYSPLASIA AT MARGIN. PRESENCE OF PERINEURAL INVASION AND QUESTIONABLE LYMPHATICS.
Bone submitted for decalcification. Supplemental report will follow.
- (F) 12 O'CLOCK MARGIN RIGHT BUCCAL:
SQUAMOUS CARCINOMA SEVERE DYSPLASIA AT MARGIN OF RESECTION DESIGNATED 5 TO 10 O'CLOCK.
- (G) RE-EXCISION RIGHT BUCCAL MARGIN:
SEVERE DYSPLASIA APPROACHING CARCINOMA IN-SITU.
- (H) RE-EXCISION RIGHT BUCCAL MARGIN #2 SINGLE SUTURE AT 6 O'CLOCK, LOWER SUTURE AT 3 O'CLOCK:
SQUAMOUS CARCINOMA.
- (I) RE-EXCISION RIGHT BUCCAL MUCOSA:
Focal high-grade dysplasia approaching carcinoma in-situ with margins free.
- (J) NEW MARGIN RIGHT BUCCAL MUCOSA:
Squamous mucosa, no tumor present.
Papillary cystadenoma in submucosa.

[page 2 of 3]
mandible (8.0 cm x 2.0 cm), six teeth, attached mucosa and soft tissues.

A 1.5 cm ulcerated, raised and roughened lesion is present on the buccal mucosa posterior to the most posterior tooth and extends to the anterior gingival surface of the posterior sixth and fifth tooth. This lesion is located 0.7 cm from the lateral resection margin, 3.0 cm from the medial resection margin, 2.5 cm from the posterior resection margin, 0.9 cm from the anterior resection margin, and 1.3 cm from the deep resection margin. The mandible is intact, and there is no gross evidence of tumor invasion into bone.

The mucosal resection margins were submitted in toto for frozen section. The bony margins come at a later date after processing by the Bone Lab.

INK CODE: Green - anterior. Yellow - lateral. Blue - posterior. Red - medial. Black - deep.

SECTION CODE: E10-E14, cross section through tumor; E15, representative deep resection margin.

*FS/DX: INVASIVE SQUAMOUS CARCINOMA. MUCOSAL MARGINS OF RESECTION FREE OF TUMOR. FOCAL MODERATE DYSPLASIA AT THE MARGIN OF RESECTION.

(F) 12 O'CLOCK MARGIN, RIGHT BUCCAL - A single circular fragment of mucosal tissue with underlying submucosa, 2.0 x 1.5 x 0.5 cm. The 12 o'clock to 6 o'clock (one-half of specimen) is painted blue. From 6 o'clock to 12 o'clock is painted yellow and the specimen is radially sectioned, submitted in toto for frozen section purposes as follows as F1, 1 o'clock; F2, 2 o'clock; F3, 3 o'clock; F4, 4 o'clock; F5, 5 o'clock; F6, 6 o'clock; F7, 7 o'clock; F8, 8 o'clock; F9, 9 o'clock; F10, 10 o'clock; F11, 11 o'clock; F12, 12 o'clock.

*FS/DX: SQUAMOUS CARCINOMA. SEVERE SQUAMOUS DYSPLASIA AND FOCALLY POSSIBLY SQUAMOUS CARCINOMA AT THE MARGIN OF RESECTION (5, 10 O'CLOCK POSITION).

(G) REEXCISION RIGHT BUCCAL MARGIN #1, 1 O'CLOCK DOUBLE SUTURE, 9 O'CLOCK SINGLE SUTURE - Consists of a mucosal-covered soft tissue piece, 2.3 x 0.3 cm.

INK CODE: Green - 1 o'clock. Black - 9 o'clock. Submitted in toto, en face for frozen section in G.

*FS/DX: SEVERE DYSPLASIA, CANNOT EXCLUDE SUPERFICIAL INVASIVE CARCINOMA.

(H) REEXCISION RIGHT BUCCAL MARGIN #2, SINGLE SUTURE 6 O'CLOCK, DOUBLE SUTURE 3 O'CLOCK - Consists of a mucosal-covered soft tissue piece, 2.5 x 0.3 x 0.3 cm.

INK CODE: Green - 6 o'clock. Black - 3 o'clock.

SECTION CODE: Submitted en face, in toto in H for frozen section.

*FS/DX: SQUAMOUS CARCINOMA.

(I) RE-EXCISION RIGHT BUCCAL MUCOSA - A single donut of mucosal tissue (3.0 x 2.0 cm) with two strings denoting the 12 o'clock position and one string denoting the 9 o'clock position. The new margins are painted blue. The specimen is radially sectioned and submitted in toto as follows.

SECTION CODE: I1, 12 o'clock to 3 o'clock; I2, 3 to 5 o'clock; I3, 5 to 7 o'clock; I4, 7 to 10 o'clock; I5, 10 to 11 o'clock; I6, 11 o'clock to 12 o'clock, all submitted for frozen section.

*FS/DX: FOCAL HIGH GRADE DYSPLASIA/CARCINOMA IN SITU.

(J) NEW MARGIN RIGHT BUCCAL - Consists of a 7.0 x 1.5 x 1.0 cm mucosal-covered soft tissue.

INK CODE: Green - 12 to 3 o'clock phase. Black - 3 to 6 o'clock phase.

SECTION CODE: J1-J4, frozen sections; J5-J7, remaining unfrozen

[page 3 of 3]
tissue. [redacted]

SNOMED CODES

M-80703 T-52010

Source: NCI Genomic Data Commons file 57fe6ef6-e9cc-4fb3-9787-c83fd4e5b9f0 (TCGA-CV-6942.9D18FD22-8E0C-4C22-9599-67B3B5DE5155.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).